Somatic mutation profile of tumor specimen C3N-02035-02 (aliquot CPT0130970006) from CPTAC case C3N-02035, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 64.5 years (23,576 days).
Specimen C3N-02035-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32023fe4-ef15-4d50-8254-3598c24b798c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02035-71 (Blood Derived Normal), aliquot CPT0180650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f847b9d-d746-4c44-94b9-139d85895036

The open-access MAF lists 966 somatic variants for this specimen: 638 protein-altering or splice-affecting, 297 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 588, Silent 297, Nonsense Mutation 36, Intron 19, Splice Region 6, RNA 5, Splice Site 4, 3'Flank 3, Frame Shift Ins 2, 5'Flank 2, 5'UTR 2, Frame Shift Del 2.

Variants (750 of 966; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 68/519 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: pathogenic / risk factor / likely pathogenic; called by muse, mutect2, varscan2
- IKZF1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 43/500 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs759124417, COSV58782650, COSV58783750; called by muse, mutect2
- NOTCH3 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 145/633 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as rs201118034, CM994179, COSV54631174, COSV54658002; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 138/700 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61963254; called by muse, mutect2, varscan2
- TP53 | c.672G>A p.E224= | Splice Region (SNP) | VAF 105/331 reads (32%) | catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.6248C>T p.S2083F (on ENST00000272895 / NM_173076.3; = p.S1765F on NM_015657.3) | Missense Mutation (SNP) | VAF 60/448 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55955359; called by muse, mutect2
- ACAN | c.7276T>C p.F2426L (on ENST00000560601 / NM_001369268.1; = p.F2350L on NM_001135.3) | Missense Mutation (SNP) | VAF 214/570 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV61355432; called by muse, mutect2, varscan2
- ACOT1 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 217/779 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs781226999; called by muse, mutect2, varscan2
- ACSM5 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 117/415 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs1567340745, COSV59370368, COSV59370530; called by muse, mutect2, varscan2
- ADAMTSL1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756246381, COSV52809345; called by muse, mutect2, varscan2
- AGAP1 | c.1469C>A p.S490* | Nonsense Mutation (SNP) | VAF 50/367 reads (14%) | catalogued as COSV58322696; called by muse, mutect2, varscan2
- AGTR1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 202/541 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200184769, COSV62557211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK2 | c.10541G>A p.G3514E | Missense Mutation (SNP) | VAF 95/724 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.813); catalogued as rs776836654; called by muse, mutect2, varscan2
- AKAP13 | c.7852C>T p.L2618F (on ENST00000394518 / NM_007200.5; = p.L2622F on NM_006738.6) | Missense Mutation (SNP) | VAF 318/871 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1016334307, COSV63465209; called by muse, mutect2, varscan2
- AL592490.1 | c.2747G>A p.G916E | Missense Mutation (SNP) | VAF 100/464 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs777669673, COSV101308314; called by muse, mutect2, varscan2
- AL713999.2 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 94/387 reads (24%) | catalogued as COSV55279929; called by muse, mutect2, varscan2
- ALK | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV66566485; called by muse, mutect2, varscan2
- ALMS1 | c.8908C>T p.Q2970* | Nonsense Mutation (SNP) | VAF 65/624 reads (10%) | catalogued as CM1515101; called by muse, mutect2, varscan2
- ALPK3 | c.3347G>A p.G1116E | Missense Mutation (SNP) | VAF 102/792 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs554737333, COSV51933309; called by muse, mutect2, varscan2
- ANK1 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 129/409 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1399054520; called by muse, mutect2, varscan2
- ANKRD12 | c.4400C>T p.S1467F | Missense Mutation (SNP) | VAF 75/537 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as rs1257667371, COSV50836886; called by muse, mutect2, varscan2
- AQP7 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 293/710 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV53025026; called by muse, mutect2, varscan2
- ARID2 | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 191/674 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); catalogued as COSV57612285; called by muse, mutect2, varscan2
- ARMCX3 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs973119559; called by muse, mutect2, varscan2
- ARSJ | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 146/492 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs915617859, COSV59537310; called by muse, mutect2, varscan2
- ASAP1 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 203/640 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs765064792; called by muse, mutect2, varscan2
- ASB18 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.784); catalogued as rs754189904; called by muse, mutect2, varscan2
- ASPRV1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 185/611 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57227543; called by muse, mutect2, varscan2
- ASXL3 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52472804; called by muse, mutect2, varscan2
- ATP8B4 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); catalogued as COSV52723885; called by muse, mutect2, varscan2
- BRINP3 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 103/466 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs866742953, COSV66521468; called by muse, mutect2, varscan2
- C1GALT1C1 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 196/401 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as rs1388046200; called by muse, mutect2, varscan2
- C6 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 64/394 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54708223; called by muse, mutect2, varscan2
- C8orf58 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 192/559 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs370310157, COSV51516794; called by muse, mutect2, varscan2
- CA9 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 149/763 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61407940; called by muse, mutect2, varscan2
- CABP5 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 136/514 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV53152190, COSV53154049; called by muse, mutect2, varscan2
- CACNA1E | c.6368G>A p.S2123N (on ENST00000367573 / NM_001205293.3; = p.S2080N on NM_000721.4) | Missense Mutation (SNP) | VAF 91/416 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV100705408; called by muse, mutect2, varscan2
- CAPN13 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 90/352 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as rs535176898, COSV54432972; called by muse, mutect2, varscan2
- CCDC92 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 104/889 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1404252578, COSV99435251; called by muse, mutect2, varscan2
- CCKBR | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 62/602 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV58100978; called by muse, mutect2, varscan2
- CD163 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 91/387 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as COSV63131450, COSV63132028; called by muse, mutect2, varscan2
- CD22 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 51/459 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.402); catalogued as rs779809517, COSV50051240; called by muse, mutect2, varscan2
- CDC42 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 81/341 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV100212668; called by muse, mutect2, varscan2
- CDHR2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 85/534 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV56138532; called by muse, mutect2, varscan2
- CEACAM6 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 147/775 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV52267617; called by muse, mutect2, varscan2
- CFAP53 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 37/378 reads (10%) | catalogued as COSV68351824; called by muse, mutect2, varscan2
- CHRD | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 144/729 reads (20%) | catalogued as COSV99200589; called by muse, mutect2, varscan2
- CIBAR1 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs771296198, COSV63897321; called by muse, mutect2, varscan2
- CLDN25 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 92/692 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV99070334; called by muse, mutect2, varscan2
- CLEC2L | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 145/583 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs867820949; called by muse, mutect2, varscan2
- CLEC7A | c.533C>T p.S178L (on ENST00000304084 / NM_197947.3; = p.S132L on NM_022570.5) | Missense Mutation (SNP) | VAF 48/488 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53723186; called by muse, mutect2
- CNBD2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 87/453 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs200885142, COSV62586786; called by muse, mutect2, varscan2
- CNTN6 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 98/280 reads (35%) | catalogued as COSV100610555; called by muse, mutect2, varscan2
- COL12A1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 188/481 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs751589202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL18A1 | c.2755G>A p.E919K (on ENST00000359759 / NM_130444.3; = p.E684K on NM_030582.4) | Missense Mutation (SNP) | VAF 189/637 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.328); catalogued as rs375045387; called by muse, mutect2, varscan2
- COL7A1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 158/341 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs746639223, COSV60396378; called by muse, mutect2, varscan2
- COL9A1 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 180/541 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV57890147; called by muse, mutect2, varscan2
- COL9A2 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 129/566 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413933689; called by muse, mutect2, varscan2
- CPAMD8 | c.1972G>A p.G658S (on ENST00000651564; = p.G611S on NM_015692.5) | Missense Mutation (SNP) | VAF 128/582 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs1169961031; called by muse, varscan2
- CPE | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 77/305 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs145394460; called by muse, mutect2, varscan2
- CRYAB | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 63/455 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs781986102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF3R | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 205/853 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs147017250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD2 | c.7561G>A p.E2521K | Missense Mutation (SNP) | VAF 139/643 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.403); catalogued as rs1177028383, COSV53919753; called by muse, mutect2, varscan2
- CSMD2 | c.4495C>T p.L1499F | Missense Mutation (SNP) | VAF 135/539 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53907711; called by muse, mutect2, varscan2
- CSMD3 | c.10611G>A p.M3537I (on ENST00000297405 / NM_001363185.1; = p.M3368I on NM_052900.3) | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV99831444; called by muse, varscan2
- CSPG4 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 121/886 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs1159208440; called by muse, mutect2, varscan2
- CSRNP3 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 153/588 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV58784458; called by muse, mutect2, varscan2
- CTAGE6 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 93/689 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778979165, COSV69919016; called by muse, mutect2, varscan2
- CYP2C18 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 115/383 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99608694; called by muse, mutect2, varscan2
- DAB1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 128/599 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs768740738; called by muse, mutect2, varscan2
- DACT2 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 232/713 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs559080276; called by muse, mutect2, varscan2
- DCBLD2 | c.2195A>G p.Y732C | Missense Mutation (SNP) | VAF 108/757 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs571842797; called by muse, mutect2, varscan2
- DDB2 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 133/540 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs1221296817; called by muse, mutect2, varscan2
- DHRS7 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 101/401 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746313916; called by muse, mutect2, varscan2
- DIO3 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 95/578 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236381409, COSV63773343; called by muse, mutect2, varscan2
- DLL3 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 236/679 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52693503; called by muse, mutect2, varscan2
- DMBT1 | c.7252C>T p.L2418F (on ENST00000338354 / NM_001377530.1; = p.L1661F on NM_004406.3) | Missense Mutation (SNP) | VAF 179/678 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.311); catalogued as COSV57562154; called by muse, mutect2, varscan2
- DNAH11 | c.12139G>A p.E4047K | Missense Mutation (SNP) | VAF 232/636 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60943264; called by muse, mutect2, varscan2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 87/555 reads (16%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, mutect2, varscan2
- DNAH5 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99455577; called by muse, varscan2
- DNAH5 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV54223513; called by muse, varscan2
- DNAH8 | c.1845G>A p.M615I | Missense Mutation (SNP) | VAF 101/337 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV59438652; called by muse, mutect2, varscan2
- DSC1 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57151485; called by muse, mutect2, varscan2
- DSC3 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV64571815; called by muse, mutect2, varscan2
- DSCAM | c.3734C>T p.S1245F | Missense Mutation (SNP) | VAF 107/437 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68021687; called by muse, mutect2, varscan2
- DSG3 | c.1364C>T p.T455I | Missense Mutation (SNP) | VAF 99/432 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs754225178; called by muse, mutect2, varscan2
- DYNC2H1 | c.9074G>A p.G3025D | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62086998; called by muse, mutect2, varscan2
- ELAPOR2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 92/403 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs750257514, COSV67193801; called by muse, mutect2, varscan2
- EPB41L1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 156/732 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759516636, COSV52446027; called by muse, varscan2
- EPGN | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 116/341 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs747900625; called by muse, mutect2, varscan2
- EPHB2 | c.2863C>T p.R955W (on ENST00000400191 / NM_001309193.2; = p.R956W on NM_004442.7) | Missense Mutation (SNP) | VAF 132/580 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748534693, COSV65863572; called by muse, mutect2, varscan2
- ESPNL | c.2753G>A p.G918D | Missense Mutation (SNP) | VAF 122/612 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1448809001, COSV100547847; called by muse, mutect2, varscan2
- FCRL1 | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 129/556 reads (23%) | catalogued as rs1414957761; called by muse, mutect2
- FLG | c.11420G>A p.R3807K | Missense Mutation (SNP) | VAF 223/892 reads (25%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.745); catalogued as COSV64251479; called by muse, mutect2, varscan2
- FMO1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 131/543 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as rs28360412; called by muse, mutect2, varscan2
- GALNT5 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 60/370 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs144689586, COSV52036497; called by muse, mutect2, varscan2
- GAPT | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 79/504 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868344368, COSV59246662; called by muse, mutect2, varscan2
- GIMAP4 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 155/528 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs755169219, COSV55433636; called by muse, varscan2
- GLI3 | c.4624C>T p.R1542W | Missense Mutation (SNP) | VAF 78/597 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs755022753, CD150069, COSV67885690; called by muse, mutect2, varscan2
- GLMP | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 185/593 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206835651; called by muse, mutect2, varscan2
- GRID1 | c.2719G>A p.G907S | Missense Mutation (SNP) | VAF 130/518 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV100022197; called by muse, mutect2, varscan2
- GRIN2A | c.3536C>T p.S1179F | Missense Mutation (SNP) | VAF 133/525 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV58023841; called by muse, mutect2, varscan2
- GRIN2A | c.2714C>T p.S905F | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV58035058; called by muse, varscan2
- GRIN2B | c.3986G>A p.R1329Q | Missense Mutation (SNP) | VAF 178/644 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1284007424, COSV74205522; called by muse, varscan2
- GRN | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 76/587 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750344, CM071797; ClinVar: not provided; called by muse, mutect2, varscan2
- GSDMB | c.1081C>T p.P361S (on ENST00000418519 / NM_001165958.1; = p.P339S on NM_018530.2) | Missense Mutation (SNP) | VAF 167/522 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as rs747114030; called by muse, mutect2, varscan2
- H3C11 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 199/544 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as rs747792724; called by muse, mutect2, varscan2
- HAUS5 | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 185/707 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1189371564; called by muse, mutect2, varscan2
- HCK | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 140/602 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52943614, COSV99394205; called by muse, mutect2, varscan2
- HEPH | c.2758G>A p.E920K (on ENST00000343002; = p.E653K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/370 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57961362; called by muse, mutect2, varscan2
- HNF4A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 95/480 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs748452860, COSV57382487; called by muse, mutect2, varscan2
- HOXB1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 210/693 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV53317651; called by muse, mutect2, varscan2
- HTR3C | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 173/784 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100570736; called by muse, mutect2, varscan2
- IFNA1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs762951011; called by muse, varscan2
- IGLV1-44 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 48/860 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.26); catalogued as rs762320081; called by muse, mutect2
- IKZF1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs1045233686, COSV100498432, COSV58788997; called by muse, mutect2
- IL36B | c.15G>A p.R5= | Splice Region (SNP) | VAF 102/373 reads (27%) | catalogued as rs141795577; called by muse, mutect2, varscan2
- IRAG2 | c.3193G>A p.E1065K (on ENST00000636465; = p.E110K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/350 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV100611710; called by muse, mutect2, varscan2
- IRAG2 | c.3389G>A p.R1130K (on ENST00000636465; = p.R175K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/595 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs916925289; called by muse, mutect2, varscan2
- ISM1 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 172/762 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1269728342; called by muse, mutect2, varscan2
- ITPKA | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs201247256; called by muse, mutect2, varscan2
- JAKMIP3 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 125/391 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1179754838, COSV53828425; called by muse, mutect2, varscan2
- JAM2 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 146/520 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57257700; called by muse, mutect2, varscan2
- KAT14 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 149/710 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV100890055; called by muse, mutect2, varscan2
- KAT14 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 148/713 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66609322; called by muse, mutect2, varscan2
- KATNAL2 | c.1261G>A p.D421N (on ENST00000356157 / NM_001353899.1; = p.D349N on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/517 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.93); catalogued as rs566388347; called by muse, mutect2, varscan2
- KCNH7 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.166); catalogued as rs375588527, COSV59787711; called by muse, mutect2, varscan2
- KCNV1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 149/586 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV52088969; called by muse, mutect2, varscan2
- KIF1A | c.1307G>A p.R436K | Missense Mutation (SNP) | VAF 65/404 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57504148; called by muse, mutect2, varscan2
- KIR2DL1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1390141805; called by muse, mutect2, varscan2
- KIR2DL4 | c.1144C>T p.P382S (on ENST00000396284; = p.P308S on NM_001080770.2) | Missense Mutation (SNP) | VAF 192/850 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.084); catalogued as rs1413239426; called by muse, mutect2, varscan2
- KLRK1 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV53697982; called by muse, mutect2, varscan2
- KRT8 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 90/423 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs147715492, COSV53177970, COSV99509910; called by muse, mutect2, varscan2
- KRTAP10-11 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 282/920 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV58177928, COSV58178864; called by muse, mutect2, varscan2
- KRTAP5-4 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs768258305, COSV101294422; called by muse, mutect2, varscan2
- KRTAP5-6 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 256/845 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.989); catalogued as COSV66289179; called by muse, mutect2, varscan2
- L1TD1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs758908225; called by muse, mutect2, varscan2
- LATS1 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 184/447 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs750553952; called by muse, mutect2, varscan2
- LGALS4 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 129/479 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.267); catalogued as rs778174358; called by muse, mutect2, varscan2
- LIF | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 203/849 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as COSV50777102; called by muse, mutect2, varscan2
- LILRB1 | c.1607G>A p.R536Q (on ENST00000427581; = p.R486Q on NM_006669.6) | Missense Mutation (SNP) | VAF 128/732 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs760007990, COSV61117500; called by muse, varscan2
- LRGUK | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 87/371 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99604283; called by muse, mutect2, varscan2
- LRP1B | c.6137C>T p.S2046F | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1406271819; called by muse, mutect2, varscan2
- LRP1B | c.5981G>A p.G1994D | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV101257460; called by muse, mutect2, varscan2
- LRRIQ3 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV63048069; called by muse, mutect2, varscan2
- MAGEB4 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 175/398 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as COSV64396770; called by muse, mutect2, varscan2
- MAP3K19 | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 58/470 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1466408259; called by muse, mutect2, varscan2
- MARCO | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 162/534 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs777128371, COSV100503308; called by muse, mutect2, varscan2
- MECOM | c.2668G>A p.D890N (on ENST00000468789 / NM_001105078.4; = p.D1078N on NM_004991.4) | Missense Mutation (SNP) | VAF 177/418 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.395); catalogued as COSV52965862; called by muse, mutect2, varscan2
- MEGF10 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV57245575; called by muse, mutect2, varscan2
- METTL8 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 123/392 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1278029561; called by muse, mutect2, varscan2
- MEX3A | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as rs1256950031; called by muse, mutect2, varscan2
- MEX3A | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.447); catalogued as rs1478285616; called by muse, varscan2
- MIDEAS | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 89/668 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs779499610; called by muse, mutect2, varscan2
- MMP16 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 186/562 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54160965; called by muse, mutect2, varscan2
- MOB3C | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 212/777 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1033804000; called by muse, varscan2
- MORN1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 176/750 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as rs1197972712; called by muse, varscan2
- MROH2B | c.3224C>T p.S1075F | Missense Mutation (SNP) | VAF 69/561 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV68188797; called by muse, mutect2, varscan2
- MRTFA | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 119/438 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1207877854; called by mutect2, varscan2
- MUC15 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 41/412 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV99029003, COSV99846369; called by muse, mutect2, varscan2
- MUC16 | c.8932C>T p.P2978S | Missense Mutation (SNP) | VAF 128/613 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101199302; called by muse, mutect2, varscan2
- MUC5B | c.7975C>T p.P2659S | Missense Mutation (SNP) | VAF 271/1074 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV71590398; called by muse, mutect2, varscan2
- MYO18B | c.5797G>A p.E1933K | Missense Mutation (SNP) | VAF 144/585 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1329484577; called by muse, mutect2, varscan2
- MZT1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761847353, COSV64698085; called by muse, mutect2, varscan2
- NADSYN1 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 56/445 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs748164413; called by muse, mutect2, varscan2
- NCAN | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 164/765 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV53059635; called by muse, mutect2, varscan2
- NEB | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 85/361 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1221725692; called by muse, mutect2, varscan2
- NELL1 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as COSV54296468, COSV54333818; called by muse, mutect2, varscan2
- NFASC | c.3146C>T p.T1049M | Missense Mutation (SNP) | VAF 45/498 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs370138600; called by muse, mutect2
- NID2 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 109/428 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1176876803; called by muse, mutect2, varscan2
- NLGN3 | c.2335C>T p.P779S (on ENST00000358741 / NM_181303.2; = p.P759S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 207/399 reads (52%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs766078372; called by muse, mutect2, varscan2
- NLRP3 | c.2851C>T p.L951F | Missense Mutation (SNP) | VAF 42/429 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV60227707; called by muse, mutect2
- NLRP5 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 144/742 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs1011984538, COSV66762254; called by muse, mutect2, varscan2
- NMS | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 76/480 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV65258729; called by muse, mutect2, varscan2
- NOS2 | c.2111G>T p.W704L | Missense Mutation (SNP) | VAF 201/469 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100569723; called by muse, mutect2, varscan2
- NPY5R | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58453210; called by muse, mutect2, varscan2
- NSUN3 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 229/848 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs759702328; called by muse, mutect2, varscan2
- NUP98 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 91/607 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61431526; called by muse, mutect2, varscan2
- OPHN1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 104/229 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs778332586; called by muse, mutect2, varscan2
- OR10Q1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 161/646 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs772343084, COSV57472272; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 106/768 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by muse, mutect2, varscan2
- OR1M1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 139/683 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs1333032690, COSV70037636; called by muse, mutect2, varscan2
- OR2G6 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.23); catalogued as rs764665907, COSV58573865, COSV58575158; called by muse, mutect2
- OR2T1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 200/871 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV63541478, COSV63541667, COSV63542221; called by muse, mutect2, varscan2
- OR2T12 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 86/731 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as COSV58775952; called by muse, mutect2, varscan2
- OR4A16 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 118/460 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs1300867180; called by muse, varscan2
- OR51A7 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 90/702 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs906070592, COSV63788359; called by muse, mutect2, varscan2
- OR51I1 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 155/631 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV66507955; called by muse, mutect2, varscan2
- OR52J3 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 161/580 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757298367, COSV66746970; called by muse, mutect2, varscan2
- OR56A5 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 76/636 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60827819; called by muse, mutect2, varscan2
- OR6C4 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.367); catalogued as COSV67792768, COSV67793322; called by muse, mutect2, varscan2
- OR7D4 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 134/652 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs140587334, COSV58071275; called by muse, mutect2, varscan2
- OR8J1 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 107/471 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs374056669, COSV57319928; called by mutect2, varscan2
- PCDH15 | c.5476C>T p.P1826S | Missense Mutation (SNP) | VAF 129/542 reads (24%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as COSV57348839; called by muse, mutect2, varscan2
- PCDH15 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57392166; called by muse, mutect2, varscan2
- PCDHB15 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 133/553 reads (24%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs782788911, COSV50886810; called by muse, mutect2, varscan2
- PCDHB8 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 101/972 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50753618; called by muse, mutect2
- PCLO | c.13315C>T p.R4439C | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753742144; called by muse, mutect2, varscan2
- PCNX2 | c.5665G>A p.G1889R | Missense Mutation (SNP) | VAF 56/467 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99269264; called by muse, mutect2, varscan2
- PHF21A | c.853C>T p.R285C (on ENST00000418153 / NM_001101802.3; = p.R286C on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/831 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760425502, COSV99138353; called by muse, mutect2, varscan2
- PHLDA1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 121/852 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.137); catalogued as rs1422937757; called by muse, mutect2, varscan2
- PKD1L1 | c.8392G>A p.E2798K | Missense Mutation (SNP) | VAF 130/445 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs755846293, COSV51841256; called by muse, mutect2, varscan2
- PLA2R1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 108/389 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746305818; called by muse, mutect2, varscan2
- PLCD3 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs752360452, COSV59559042; called by muse, mutect2, varscan2
- PLXNA4 | c.4144G>A p.D1382N | Missense Mutation (SNP) | VAF 144/654 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs118107843, COSV58134136; called by muse, mutect2, varscan2
- POLD3 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757324048; called by muse, mutect2, varscan2
- POM121L12 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 63/684 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV68692140; called by muse, mutect2
- POTEE | c.2216G>A p.R739K | Missense Mutation (SNP) | VAF 87/482 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); catalogued as rs1376960274; called by muse, mutect2, varscan2
- POU6F2 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 76/441 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1240922902; called by muse, mutect2, varscan2
- PPP1R13B | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 53/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968897903, COSV52449070, COSV52453922; called by muse, mutect2, varscan2
- PPP1R16B | c.1685G>A p.G562D | Missense Mutation (SNP) | VAF 110/450 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.286); catalogued as COSV55376042; called by muse, mutect2, varscan2
- PRB3 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 158/920 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs748969365; called by muse, varscan2
- PRB4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 122/851 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV54396807; called by muse, mutect2, varscan2
- PRKACA | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 164/627 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58068022; called by muse, mutect2, varscan2
- PRRX1 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 107/405 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs372098442; called by muse, mutect2, varscan2
- PRSS35 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs776819854, COSV63800274; called by muse, mutect2, varscan2
- PTPRK | c.3526G>A p.E1176K (on ENST00000368215 / NM_001291984.2; = p.E1177K on NM_002844.4) | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63890744, COSV63895574; called by muse, mutect2, varscan2
- PXDNL | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 114/435 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1390297647, COSV62487318; called by muse, mutect2, varscan2
- RAD23A | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 168/707 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as rs1288610281; called by muse, mutect2, varscan2
- RCL1 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 96/681 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1463856980, COSV100762118; called by muse, mutect2, varscan2
- RFX4 | c.1085C>T p.T362I (on ENST00000392842 / NM_213594.3; = p.T268I on NM_032491.6) | Missense Mutation (SNP) | VAF 136/520 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV57575883; called by muse, mutect2, varscan2
- RGPD2 | c.4141G>A p.D1381N | Missense Mutation (SNP) | VAF 50/521 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.753); catalogued as COSV100552817; called by muse, mutect2, varscan2
- RGPD4 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs746643497, COSV100736579; called by muse, mutect2, varscan2
- RNF10 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 79/504 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs141882801; called by muse, mutect2, varscan2
- RNF216 | c.431C>T p.S144F (on ENST00000425013 / NM_207116.3; = p.S201F on NM_207111.4) | Missense Mutation (SNP) | VAF 301/766 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); catalogued as rs767582435; called by muse, mutect2, varscan2
- ROBO2 | c.2258G>A p.S753N | Missense Mutation (SNP) | VAF 384/887 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs1410965548; called by muse, mutect2, varscan2
- RPGRIP1 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 156/557 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs770870865, COSV52850814; called by muse, mutect2, varscan2
- RPS6KA6 | c.99G>T p.M33I | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs1322814646; called by muse, mutect2, varscan2
- RYR1 | c.3883C>T p.Q1295* | Nonsense Mutation (SNP) | VAF 142/744 reads (19%) | catalogued as COSV62113286; called by muse, mutect2, varscan2
- RYR2 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 63/613 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs267598436, COSV63689111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SARS1 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 110/463 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs138598293, COSV99320960; called by muse, mutect2, varscan2
- SCAF11 | c.2630G>T p.R877I | Missense Mutation (SNP) | VAF 97/485 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV101014311; called by muse, mutect2, varscan2
- SCN2A | c.2216G>A p.W739* | Nonsense Mutation (SNP) | VAF 73/533 reads (14%) | catalogued as rs1553574555; called by muse, mutect2, varscan2
- SEC16B | c.3020C>T p.S1007F | Missense Mutation (SNP) | VAF 63/435 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs542193198, COSV57625691; called by muse, mutect2, varscan2
- SEC16B | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 158/582 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57627558; called by muse, mutect2, varscan2
- SERPINA7 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 164/392 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1178965925; called by muse, mutect2, varscan2
- SERPINB10 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 129/510 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs267605235, COSV53072971; called by muse, mutect2, varscan2
- SERPINB11 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 162/573 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1476548034; called by muse, mutect2, varscan2
- SETD1B | c.3221C>T p.T1074I | Missense Mutation (SNP) | VAF 164/666 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.157); catalogued as rs1473490380; called by muse, varscan2
- SFRP4 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 148/587 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.194); catalogued as rs924433228, COSV71412364; called by muse, mutect2, varscan2
- SIGLEC7 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 108/505 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as rs868116272; called by muse, mutect2, varscan2
- SIRT6 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 158/802 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs749208802; called by muse, mutect2, varscan2
- SLC13A1 | c.1108C>G p.P370A | Missense Mutation (SNP) | VAF 93/501 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV52015242, COSV52015287; called by muse, mutect2, varscan2
- SLC24A3 | c.1543A>C p.T515P | Missense Mutation (SNP) | VAF 32/704 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60127738; called by muse, mutect2
- SLC26A9 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 98/400 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs766171017; called by muse, mutect2, varscan2
- SLC27A6 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as COSV52483902, COSV99321937; called by muse, mutect2, varscan2
- SLC30A8 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746249658; called by muse, mutect2, varscan2
- SLC38A1 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67063648; called by muse, mutect2, varscan2
- SLC6A17 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 150/635 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs147200498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9B1 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 87/457 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748586746, COSV99599704; called by muse, mutect2, varscan2
- SLIT2 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 89/316 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as COSV56567437; called by muse, mutect2, varscan2
- SP140 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs1431533007, COSV59455289; called by muse, mutect2, varscan2
- SPAM1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 154/682 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56141089; called by muse, mutect2, varscan2
- SPATA31A1 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 66/678 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1293145523; called by muse, mutect2, varscan2
- SPHKAP | c.4852G>A p.E1618K (on ENST00000392056 / NM_001142644.2; = p.E1589K on NM_030623.3) | Missense Mutation (SNP) | VAF 90/513 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV60885643; called by muse, mutect2, varscan2
- SPTA1 | c.7188G>A p.M2396I | Missense Mutation (SNP) | VAF 81/462 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs376052117, COSV63523813; called by muse, mutect2, varscan2
- SPTA1 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 126/497 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs1341147461; called by muse, mutect2, varscan2
- STEAP3 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 84/660 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868436103; called by muse, mutect2, varscan2
- STYXL2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 128/524 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as rs1256958001, COSV54810634; called by mutect2, varscan2
- STYXL2 | c.2375G>A p.S792N | Missense Mutation (SNP) | VAF 152/571 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV54809171; called by muse, mutect2, varscan2
- SUGCT | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747138567, COSV59333293; called by muse, mutect2
- SYCP1 | c.357G>A p.W119* | Nonsense Mutation (SNP) | VAF 64/337 reads (19%) | catalogued as COSV65696720, COSV65700485; called by muse, mutect2, varscan2
- TBC1D14 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 221/639 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.343); catalogued as COSV101298873; called by muse, mutect2, varscan2
- TCTN1 | c.1541C>G p.T514S (on ENST00000551590 / NM_001173975.3; = p.T500S on NM_024549.6) | Missense Mutation (SNP) | VAF 155/510 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54374361; called by muse, mutect2, varscan2
- TECPR1 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 67/482 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs764897072, COSV101130765; called by muse, mutect2, varscan2
- TENM3 | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 159/523 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs538115479, COSV69304408; called by muse, mutect2, varscan2
- TENM4 | c.2005G>A p.G669S | Missense Mutation (SNP) | VAF 169/629 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.516); catalogued as rs1156794390; called by muse, mutect2, varscan2
- TEX13C | c.2836C>T p.Q946* | Nonsense Mutation (SNP) | VAF 122/329 reads (37%) | catalogued as COSV66745122; called by muse, mutect2, varscan2
- TMEM266 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 59/682 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.285); catalogued as rs376055659; called by muse, mutect2
- TNXB | c.6970G>A p.E2324K (on ENST00000647633; = p.E2077K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/474 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV64476745; called by muse, mutect2, varscan2
- TOX2 | c.1451C>T p.S484L (on ENST00000358131 / NM_001098798.2; = p.S460L on NM_032883.3) | Missense Mutation (SNP) | VAF 109/563 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs779716371, COSV57883132; called by muse, mutect2, varscan2
- TRPC5 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as COSV53298495; called by muse, mutect2, varscan2
- TRPM6 | c.5677G>A p.E1893K | Missense Mutation (SNP) | VAF 190/586 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750841378, COSV62502669, COSV62502847; called by muse, mutect2, varscan2
- TRPV5 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 173/773 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV54686528; called by muse, mutect2, varscan2
- UBASH3A | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764539311; called by muse, mutect2
- ULK3 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 130/709 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs371058363; called by muse, mutect2, varscan2
- UNC13C | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 128/502 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52860266; called by muse, mutect2, varscan2
- USP30 | c.884C>A p.T295K | Missense Mutation (SNP) | VAF 73/518 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as COSV57450910; called by muse, mutect2, varscan2
- USP5 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 113/462 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1488368204; called by muse, mutect2, varscan2
- VAT1L | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56822238; called by muse, mutect2, varscan2
- VWDE | c.3587C>G p.S1196C | Missense Mutation (SNP) | VAF 147/762 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV51723870; called by muse, mutect2, varscan2
- WDR87 | c.6529G>A p.D2177N | Missense Mutation (SNP) | VAF 126/632 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.236); catalogued as rs1005429821; called by muse, mutect2, varscan2
- WNK1 | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 167/645 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV60043815; called by muse, mutect2, varscan2
- YLPM1 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 237/872 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.28); catalogued as COSV53118902; called by muse, mutect2, varscan2
- ZC3H4 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 159/746 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV53411041; called by muse, mutect2, varscan2
- ZFPM2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 140/482 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV65873093; called by muse, mutect2, varscan2
- ZFR | c.2788C>T p.R930* | Nonsense Mutation (SNP) | VAF 68/391 reads (17%) | catalogued as rs1257741972, COSV99416558; called by muse, mutect2, varscan2
- ZNF208 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 97/502 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV68106252; called by muse, mutect2, varscan2
- ZNF215 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 41/347 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs1487411169; called by muse, mutect2, varscan2
- ZNF257 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 133/607 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV71306544; called by muse, mutect2, varscan2
- ZNF316 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 386/935 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs932182611; called by muse, mutect2, varscan2
- ZNF354A | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100234356, COSV100234468; called by muse, mutect2, varscan2
- ZNF479 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.056); catalogued as COSV100482784; called by muse, mutect2, varscan2
- ZNF534 | c.829C>T p.H277Y (on ENST00000332323 / NM_001143939.3; = p.H264Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/578 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56515480; called by muse, mutect2, varscan2
- ZNF648 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 155/639 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60571059; called by muse, mutect2, varscan2
- ZNF667 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 120/484 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52633198; called by muse, mutect2, varscan2
- ZNF676 | c.988G>A p.E330K (on ENST00000650058; = p.E298K on NM_001001411.3) | Missense Mutation (SNP) | VAF 156/920 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.143); catalogued as rs1392765155; called by muse, mutect2, varscan2
- ZNF728 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 73/453 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99077708; called by muse, mutect2, varscan2
- ZNF777 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 170/814 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs1240857282, COSV56099583; called by muse, mutect2, varscan2
- ZNF850 | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 152/597 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs529853552, COSV74024344; called by muse, mutect2, varscan2
- ZP1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 201/779 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1402567426; called by muse, mutect2, varscan2
- ZSCAN5C | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 76/490 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.646); catalogued as rs765294655; called by muse, mutect2
- ABCC6 | c.345+1G>A p.X115_splice | Splice Site (SNP) | VAF 50/213 reads (23%) | called by muse, mutect2, varscan2
- ABHD16B | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 191/829 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- AC010255.2 | c.109A>T p.N37Y | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAN | c.6493C>T p.P2165S | Missense Mutation (SNP) | VAF 329/798 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ADAP2 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 181/489 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ADARB1 | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 188/604 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADARB1 | c.1550G>A p.R517K (on ENST00000360697 / NM_001346687.2; = p.R477K on NM_001112.4) | Missense Mutation (SNP) | VAF 59/591 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRE5 | c.935C>T p.P312L (on ENST00000242786 / NM_078481.4; = p.P219L on NM_001784.5) | Missense Mutation (SNP) | VAF 146/612 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRF1 | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 245/658 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ADGRL4 | c.1711A>T p.I571F | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRV1 | c.10561C>T p.L3521F | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ADH4 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 116/394 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADSS2 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF1 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 164/562 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- AKR1D1 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 85/407 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ALKBH8 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 87/721 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- AMACR | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 76/416 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AMDHD2 | c.102_117del p.G35Tfs*88 | Frame Shift Del (DEL) | VAF 128/452 reads (28%) | called by mutect2, pindel, varscan2
- ANK1 | c.2072G>A p.G691D | Missense Mutation (SNP) | VAF 139/491 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANKRD33B | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 334/1024 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP002495.1 | c.319C>T p.H107Y (on ENST00000528511; = p.H38Y on NM_001375848.1) | Missense Mutation (SNP) | VAF 122/451 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- APBA2 | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 254/895 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP20 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 137/534 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ARHGAP44 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 165/541 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 200/827 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ARL2BP | c.359C>G p.A120G | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ARMCX3 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASAH2 | c.1543C>T p.H515Y | Missense Mutation (SNP) | VAF 135/471 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASH1L | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 107/498 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ASNS | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 100/460 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ATG10 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ATG10 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 101/463 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ATG4D | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 191/842 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP13A4 | c.3577G>A p.E1193K | Missense Mutation (SNP) | VAF 79/396 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ATP8B2 | c.2975C>T p.A992V (on ENST00000672630; = p.A959V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/515 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ATRAID | c.755C>T p.S252L (on ENST00000611786; = p.S139L on NM_016085.5) | Missense Mutation (SNP) | VAF 50/512 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); called by muse, mutect2
- AZU1 | c.597G>A p.G199= | Splice Region (SNP) | VAF 157/669 reads (23%) | called by muse, mutect2, varscan2
- BEST1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 113/420 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- BNC1 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 272/717 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- BOP1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 148/478 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- BTG3 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 109/509 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- BTG3 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 107/505 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- C10orf71 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 160/497 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- C12orf50 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 76/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2orf16 | c.2087T>C p.L696S | Missense Mutation (SNP) | VAF 149/484 reads (31%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CA13 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CA8 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAMSAP1 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 290/899 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CATSPER1 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 117/454 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC168 | c.12653G>A p.R4218K | Missense Mutation (SNP) | VAF 121/705 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CCR3 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 233/650 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CD1C | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CD1E | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 50/479 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CD8B | c.641C>T p.S214L (on ENST00000331469 / NM_172213.4; = p.S184L on NM_172102.4) | Missense Mutation (SNP) | VAF 112/428 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2
- CDKN1C | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 221/756 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CFAP47 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHRNA10 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 104/795 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CILP | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 65/390 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CLCNKA | c.2017-1G>A p.X673_splice | Splice Site (SNP) | VAF 70/376 reads (19%) | called by muse, mutect2, varscan2
- CLDN14 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 35/536 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLU | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 207/600 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNGB3 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 61/233 reads (26%) | called by muse, mutect2, varscan2
- CNTN3 | c.2469G>A p.W823* | Nonsense Mutation (SNP) | VAF 133/705 reads (19%) | called by muse, mutect2, varscan2
- COG8 | c.1115A>T p.Q372L | Missense Mutation (SNP) | VAF 167/538 reads (31%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- COL1A2 | c.3152G>T p.G1051V | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL2A1 | c.2969G>A p.G990D | Missense Mutation (SNP) | VAF 62/522 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- COL4A4 | c.4405G>A p.V1469I | Missense Mutation (SNP) | VAF 91/609 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- COL4A4 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 117/621 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 98/424 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COL5A3 | c.4262G>A p.G1421E | Missense Mutation (SNP) | VAF 177/743 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL8A1 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 264/807 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- COL9A1 | c.2669G>A p.G890E | Missense Mutation (SNP) | VAF 185/587 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPQ | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CR1 | c.1065G>A p.V355= (on ENST00000367051; = p.V805= on NM_000651.6) | Splice Region (SNP) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- CREBBP | c.5522C>T p.P1841L | Missense Mutation (SNP) | VAF 199/586 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREG2 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CRYZ | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 80/366 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CSF2RB | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 169/786 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CSF2RB | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 208/853 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CSMD2 | c.8140G>A p.G2714R | Missense Mutation (SNP) | VAF 162/729 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CTC1 | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 164/405 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- CTNNA3 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CUX1 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 49/470 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP4F11 | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 100/448 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DEPDC7 | c.88del p.Q30Rfs*14 (on ENST00000241051 / NM_001077242.2; = p.Q21Rfs*14 on NM_139160.2) | Frame Shift Del (DEL) | VAF 77/359 reads (21%) | called by mutect2, pindel, varscan2
- DHRS7 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.4753G>A p.D1585N (on ENST00000409039; = p.D1524N on NM_207437.3) | Missense Mutation (SNP) | VAF 74/552 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH11 | c.6672G>A p.W2224* | Nonsense Mutation (SNP) | VAF 42/462 reads (9%) | called by muse, mutect2
- DNAH12 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 182/581 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNMT3A | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 190/701 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DOCK2 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 45/344 reads (13%) | called by muse, mutect2, varscan2
- DOP1A | c.3239C>T p.S1080F | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DSG4 | c.2942G>A p.S981N | Missense Mutation (SNP) | VAF 154/554 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, varscan2
- DSP | c.7445C>T p.A2482V | Missense Mutation (SNP) | VAF 61/509 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- DTX1 | c.194T>A p.V65E | Missense Mutation (SNP) | VAF 194/644 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYNC2H1 | c.6706G>A p.G2236S | Missense Mutation (SNP) | VAF 57/458 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EHD3 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 100/797 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EIF2AK2 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ELF1 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 230/743 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ELOA3B | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 150/2004 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2
- ELSPBP1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 130/699 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMB | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- EMID1 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 174/867 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ENOX1 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ENPP3 | c.1636C>A p.P546T | Missense Mutation (SNP) | VAF 200/565 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ENTPD6 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 173/875 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EPHB6 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 163/753 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- EXO1 | c.2295dup p.L766Afs*15 | Frame Shift Ins (INS) | VAF 104/483 reads (22%) | called by mutect2, pindel, varscan2
- FAM186A | c.4043G>A p.G1348E | Missense Mutation (SNP) | VAF 239/956 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- FAM186A | c.4042G>A p.G1348R | Missense Mutation (SNP) | VAF 234/954 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FAM228B | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FBXL18 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 255/1291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FOXL1 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 183/540 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FREM2 | c.3457C>T p.H1153Y | Missense Mutation (SNP) | VAF 136/529 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FRMPD1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 295/776 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- FZD1 | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 103/712 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABBR2 | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 265/683 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GABRR2 | c.12dup p.T5Yfs*38 | Frame Shift Ins (INS) | VAF 95/316 reads (30%) | called by mutect2, pindel, varscan2
- GARRE1 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 147/637 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- GBP5 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 98/447 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- GCFC2 | c.528T>G p.D176E | Missense Mutation (SNP) | VAF 78/604 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI2 | c.4497G>A p.M1499I (on ENST00000361492 / NM_001374353.1; = p.M1516I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/637 reads (13%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- GLYATL3 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 160/550 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA6L6 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 24/608 reads (4%) | called by muse, mutect2
- GPR174 | c.881T>A p.F294Y | Missense Mutation (SNP) | VAF 140/325 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR33 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, varscan2
- GRIA1 | c.1916C>T p.T639I | Missense Mutation (SNP) | VAF 101/557 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN2A | c.4121A>C p.D1374A | Missense Mutation (SNP) | VAF 181/589 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- GRP | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 75/633 reads (12%) | called by muse, mutect2, varscan2
- GUF1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- HAVCR1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 93/537 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HHAT | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 110/523 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIP1 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 110/480 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HMGCS2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 108/434 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 112/480 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HRG | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 254/1072 reads (24%) | called by muse, mutect2, varscan2
- HSPB3 | c.238T>C p.F80L | Missense Mutation (SNP) | VAF 78/595 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFNA13 | c.543C>G p.N181K | Missense Mutation (SNP) | VAF 94/334 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IFT172 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 77/581 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- IGHA1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- IGHV5-51 | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- IGLC7 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 122/481 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGLV1-47 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 84/404 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IKZF2 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPG1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INCENP | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 49/463 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INHBB | c.902A>G p.N301S | Missense Mutation (SNP) | VAF 79/713 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSC | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 155/505 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- INSRR | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 47/499 reads (9%) | called by muse, mutect2
- IRF4 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ISL1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ISM2 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 105/669 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ITK | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 69/464 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR3 | c.4730C>T p.P1577L | Missense Mutation (SNP) | VAF 201/554 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- IVL | c.1020G>T p.E340D | Missense Mutation (SNP) | VAF 163/680 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- KANK4 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 160/687 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- KCNH1 | c.2420G>A p.G807E (on ENST00000271751 / NM_172362.3; = p.G780E on NM_002238.4) | Missense Mutation (SNP) | VAF 89/727 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0513 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 156/456 reads (34%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- KIDINS220 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 77/664 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- KLHL30 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- KLHL4 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 191/407 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KNL1 | c.3679T>C p.F1227L (on ENST00000346991 / NM_170589.5; = p.F1201L on NM_144508.5) | Missense Mutation (SNP) | VAF 122/387 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KRT10 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 122/933 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KRTAP19-7 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 29/317 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.304); called by muse, mutect2
- LACTBL1 | c.389+2G>A p.X130_splice (on ENST00000618559; = p.D160N on NM_001289974.2) | Splice Site (SNP) | VAF 218/823 reads (26%) | called by muse, mutect2, varscan2
- LCOR | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 165/432 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- LDLRAP1 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 54/624 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- LRP1B | c.8986G>A p.G2996R | Missense Mutation (SNP) | VAF 116/490 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC70 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGI1 | c.3892G>A p.D1298N | Missense Mutation (SNP) | VAF 304/1039 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGI2 | c.2770C>T p.H924Y | Missense Mutation (SNP) | VAF 149/611 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- MALRD1 | c.5851G>A p.E1951K | Missense Mutation (SNP) | VAF 137/529 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MAP3K19 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 139/526 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP7D2 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 169/368 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAST1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 104/508 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MCTP1 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 77/469 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MDC1 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 304/884 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- MED12 | c.5804C>T p.S1935F | Missense Mutation (SNP) | VAF 159/327 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MED25 | c.1204_1205insAAAGCGGGGTCCT p.W402* | Nonsense Mutation (INS) | VAF 82/595 reads (14%) | called by pindel, varscan2
- MID2 | c.1415G>A p.R472K | Missense Mutation (SNP) | VAF 126/322 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- MIGA2 | c.290T>A p.V97D | Missense Mutation (SNP) | VAF 108/583 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MUC16 | c.25090G>A p.E8364K | Missense Mutation (SNP) | VAF 161/701 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MUC16 | c.22799C>T p.S7600F | Missense Mutation (SNP) | VAF 130/594 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.206); called by muse, varscan2
- MUC17 | c.13315G>A p.G4439R | Missense Mutation (SNP) | VAF 138/509 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- MYH8 | c.4975C>T p.H1659Y | Missense Mutation (SNP) | VAF 159/436 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- MYO18B | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 162/728 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MYO9B | c.4928C>T p.P1643L | Missense Mutation (SNP) | VAF 125/530 reads (24%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NAALADL2 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 48/566 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2
- NBEAL1 | c.3914A>G p.K1305R | Missense Mutation (SNP) | VAF 22/515 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- NBPF11 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 69/589 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NBR1 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 91/805 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCKAP5 | c.3439C>T p.P1147S | Missense Mutation (SNP) | VAF 183/530 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.16014A>C p.E5338D | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NFE2L3 | c.1181T>A p.L394* | Nonsense Mutation (SNP) | VAF 233/492 reads (47%) | called by muse, mutect2, varscan2
- NLRP2 | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 120/635 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRP2 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 206/715 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXPE2 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 76/632 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ODF3B | c.171C>A p.F57L | Missense Mutation (SNP) | VAF 185/783 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPN5 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 145/422 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13H1 | c.74A>T p.D25V | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T34 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 32/708 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.38); called by muse, mutect2
- OR51T1 | c.643T>A p.F215I | Missense Mutation (SNP) | VAF 139/513 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OSBPL7 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 131/413 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOG | c.6112G>A p.E2038K | Missense Mutation (SNP) | VAF 160/613 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- P3H1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 148/689 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARP14 | c.4093A>T p.K1365* | Nonsense Mutation (SNP) | VAF 218/544 reads (40%) | called by muse, mutect2, varscan2
- PCDHA4 | c.2216T>A p.L739Q | Missense Mutation (SNP) | VAF 79/608 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PCDHB11 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 114/787 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PCDHGA3 | c.1816T>C p.Y606H | Missense Mutation (SNP) | VAF 123/921 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE4DIP | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PGM1 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 168/658 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PHKA1 | c.2229+1G>A p.X743_splice | Splice Site (SNP) | VAF 81/192 reads (42%) | called by muse, mutect2, varscan2
- PHLDB3 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 100/422 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PHRF1 | c.1646C>T p.S549F (on ENST00000264555 / NM_001286581.2; = p.S548F on NM_020901.4) | Missense Mutation (SNP) | VAF 147/571 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PHYHIPL | c.1036G>C p.A346P | Missense Mutation (SNP) | VAF 131/468 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PI16 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 193/520 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PIP4K2B | c.735T>G p.N245K | Missense Mutation (SNP) | VAF 70/566 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.058); called by mutect2, varscan2
- PLAUR | c.409T>C p.C137R | Missense Mutation (SNP) | VAF 148/714 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG6 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 78/550 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- POTEC | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, varscan2
- POTEJ | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); called by mutect2, varscan2
- PPHLN1 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 120/497 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF4 | c.676T>C p.F226L | Missense Mutation (SNP) | VAF 210/987 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKAG2 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 87/522 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- PRKRIP1 | c.203T>A p.M68K | Missense Mutation (SNP) | VAF 83/591 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PRMT7 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 166/485 reads (34%) | called by muse, mutect2, varscan2
- PROZ | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 111/414 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PSD | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 193/660 reads (29%) | called by muse, mutect2, varscan2
- PSG9 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 156/693 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN20 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTPN22 | c.1967G>A p.W656* (on ENST00000359785 / NM_001193431.2; = p.W601* on NM_012411.5) | Nonsense Mutation (SNP) | VAF 93/416 reads (22%) | called by muse, mutect2, varscan2
- PTPRU | c.3266C>T p.T1089I | Missense Mutation (SNP) | VAF 103/480 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PWWP2A | c.1332T>A p.N444K | Missense Mutation (SNP) | VAF 92/573 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABGEF1 | c.1348G>T p.D450Y (on ENST00000439720 / NM_001287061.2; = p.D437Y on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/790 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- RABGGTA | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 62/429 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- RAI1 | c.3793G>C p.G1265R | Missense Mutation (SNP) | VAF 207/606 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RAPGEF5 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 68/617 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RASSF2 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 146/604 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- RGPD3 | c.5243G>A p.G1748E | Missense Mutation (SNP) | VAF 128/545 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- RGS9 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- RNF17 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF212B | c.506A>C p.H169P | Missense Mutation (SNP) | VAF 112/432 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- RP1 | c.1602A>T p.K534N | Missense Mutation (SNP) | VAF 94/330 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- RPRD2 | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 172/727 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, varscan2
- RPS21 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 167/727 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- RRAGA | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 110/347 reads (32%) | called by muse, mutect2, varscan2
- RRBP1 | c.2615C>T p.S872F (on ENST00000377813 / NM_001365613.2; = p.S439F on NM_004587.3) | Missense Mutation (SNP) | VAF 152/616 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RRBP1 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 172/712 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RXFP1 | c.972G>A p.L324= | Splice Region (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- S100A9 | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 48/381 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SACM1L | c.378G>C p.L126F | Missense Mutation (SNP) | VAF 41/1186 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2
- SACM1L | c.468G>C p.M156I | Missense Mutation (SNP) | VAF 36/968 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.065); called by muse, mutect2
- SEL1L2 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 151/639 reads (24%) | called by muse, mutect2, varscan2
- SEMA5B | c.2432G>A p.G811D | Missense Mutation (SNP) | VAF 401/824 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- SF3B2 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 88/935 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.981); called by muse, mutect2
- SGO1 | c.1484G>A p.R495K (on ENST00000263753 / NM_001012410.5; = p.R226K on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH2D3A | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 141/703 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SHANK2 | c.5425G>A p.D1809N | Missense Mutation (SNP) | VAF 58/577 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHC4 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.4252C>T p.P1418S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SKAP2 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SLC13A1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 92/496 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SLC15A2 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 147/384 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC26A2 | c.1462A>T p.I488F | Missense Mutation (SNP) | VAF 80/517 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC26A8 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 87/552 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SLC27A3 | c.1757C>T p.S586F (on ENST00000271857; = p.S458F on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/617 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC6A12 | c.382T>G p.Y128D | Missense Mutation (SNP) | VAF 78/495 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SLIT2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 124/439 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK6 | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 123/425 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SMU1 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 232/606 reads (38%) | called by muse, mutect2, varscan2
- SNORC | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 125/685 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- SP7 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 189/794 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA31A1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 80/703 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPDYE6 | c.1149G>A p.E383= | Splice Region (SNP) | VAF 73/672 reads (11%) | called by muse, varscan2
- SPOCD1 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 132/540 reads (24%) | called by muse, mutect2, varscan2
- SPON1 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 128/435 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPON1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 123/428 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN1 | c.3046C>T p.Q1016* | Nonsense Mutation (SNP) | VAF 108/823 reads (13%) | called by muse, mutect2
- SRGAP3 | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 187/541 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SRSF12 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 153/441 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SSX2IP | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 87/374 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- STXBP2 | c.409T>C p.F137L | Missense Mutation (SNP) | VAF 95/468 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- STXBP4 | c.1653G>T p.Q551H | Missense Mutation (SNP) | VAF 121/379 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- STYXL2 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 69/569 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- SULT1C4 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- SV2B | c.1963G>A p.V655I | Missense Mutation (SNP) | VAF 105/745 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SYNPO2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 170/555 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TAOK3 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 83/325 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TENM1 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- TGFB3 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 120/587 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- THAP4 | c.663T>G p.F221L | Missense Mutation (SNP) | VAF 79/479 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TLR4 | c.1417C>T p.L473F (on ENST00000355622 / NM_138554.5; = p.L433F on NM_003266.4) | Missense Mutation (SNP) | VAF 145/456 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132D | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 70/595 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TMEM39B | c.506C>A p.T169K | Missense Mutation (SNP) | VAF 180/766 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TMEM72 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 180/541 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMPRSS7 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 653/1132 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TNXB | c.3820G>A p.E1274K (on ENST00000647633; = p.E1027K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 162/517 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TOLLIP | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 221/699 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TOP1 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 139/636 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TPD52L3 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 84/553 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- TPTE | c.1052C>T p.A351V (on ENST00000618007 / NM_199261.4; = p.A333V on NM_199259.4) | Missense Mutation (SNP) | VAF 29/492 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.665); called by muse, mutect2
- TRBV28 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 101/403 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- TRGV8 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 118/464 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRPC5 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 160/324 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTLL10 | c.1229C>T p.S410F (on ENST00000379289 / NM_001130045.2; = p.S337F on NM_153254.3) | Missense Mutation (SNP) | VAF 177/682 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- TYROBP | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 118/481 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- UBE2J2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 111/457 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- UBXN2A | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 59/493 reads (12%) | called by muse, mutect2, varscan2
- UNC5B | c.2828G>A p.G943E | Missense Mutation (SNP) | VAF 102/358 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UPP2 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 132/473 reads (28%) | called by muse, mutect2, varscan2
- USP17L4 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 111/431 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- USP5 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- UTS2 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 87/353 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- WARS1 | c.1229A>T p.D410V | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR11 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 113/372 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- WDR72 | c.1936G>A p.G646S | Missense Mutation (SNP) | VAF 118/452 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAN | c.3721C>T p.P1241S | Missense Mutation (SNP) | VAF 67/523 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBED9 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 213/676 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- ZFHX2 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 175/705 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFHX2 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 172/704 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFP2 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 76/455 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN2 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 104/377 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMIZ2 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 52/628 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZMYM1 | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 81/423 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZNF185 | c.1705A>G p.S569G | Missense Mutation (SNP) | VAF 134/280 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF215 | c.1116T>A p.S372R | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF358 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 221/766 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- ZNF48 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 176/527 reads (33%) | called by muse, mutect2, varscan2
- ZNF497 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 198/923 reads (21%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZNF630 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 177/382 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZNF70 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 125/632 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF720 | c.196A>G p.K66E | Missense Mutation (SNP) | VAF 163/497 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF98 | c.555A>T p.K185N | Missense Mutation (SNP) | VAF 76/389 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2
- ZYG11B | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 138/661 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ABCA4 | c.216G>A p.G72= | Silent (SNP) | VAF 161/692 reads (23%) | called by muse, mutect2, varscan2
- ABI3 | c.714C>T p.P238= | Silent (SNP) | VAF 300/849 reads (35%) | catalogued as COSV56800335; called by muse, mutect2, varscan2
- ACE | c.3180C>T p.I1060= | Silent (SNP) | VAF 174/470 reads (37%) | catalogued as rs754344947, COSV52003209; called by muse, varscan2
- ACSM1 | c.21C>T p.F7= | Silent (SNP) | VAF 101/348 reads (29%) | catalogued as COSV54637509; called by muse, mutect2, varscan2
- ACTBL2 | c.726A>G p.E242= | Silent (SNP) | VAF 107/579 reads (18%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.1191C>T p.I397= | Silent (SNP) | VAF 99/606 reads (16%) | catalogued as rs369731938; called by muse, mutect2, varscan2
- ADCY10 | c.2688C>T p.S896= | Silent (SNP) | VAF 100/341 reads (29%) | catalogued as COSV63240990; called by muse, mutect2, varscan2
- ADGRV1 | c.12582C>T p.F4194= | Silent (SNP) | VAF 73/458 reads (16%) | catalogued as COSV67984984; called by muse, mutect2, varscan2
- AL592490.1 | c.2748G>A p.G916= | Silent (SNP) | VAF 100/462 reads (22%) | called by muse, mutect2, varscan2
- ALPK1 | c.382C>T p.L128= | Silent (SNP) | VAF 139/469 reads (30%) | called by muse, mutect2, varscan2
- AMPD1 | c.1482G>A p.R494= | Silent (SNP) | VAF 70/374 reads (19%) | catalogued as rs1371202947; called by muse, mutect2, varscan2
- ANKRD30B | c.1011G>A p.R337= | Silent (SNP) | VAF 95/653 reads (15%) | catalogued as COSV62814000; called by muse, mutect2, varscan2
- APBA2 | c.1302C>T p.S434= | Silent (SNP) | VAF 60/569 reads (11%) | catalogued as COSV101258200; called by muse, mutect2, varscan2
- APOA4 | c.129G>A p.K43= | Silent (SNP) | VAF 62/512 reads (12%) | called by muse, mutect2, varscan2
- ART4 | c.285G>A p.R95= | Silent (SNP) | VAF 149/610 reads (24%) | called by muse, mutect2, varscan2
- ATG9B | c.750C>T p.T250= | Silent (SNP) | VAF 167/774 reads (22%) | catalogued as COSV100939942; called by muse, mutect2, varscan2
- ATP13A1 | c.879G>A p.K293= | Silent (SNP) | VAF 79/594 reads (13%) | catalogued as COSV99366832; called by muse, mutect2, varscan2
- ATP8B2 | c.2976C>T p.A992= (on ENST00000672630; = p.A959= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 134/517 reads (26%) | called by muse, mutect2, varscan2
- BICRA | c.3208C>T p.L1070= | Silent (SNP) | VAF 112/573 reads (20%) | catalogued as rs1158546195; called by muse, mutect2, varscan2
- BPIFB4 | c.777G>A p.G259= | Silent (SNP) | VAF 131/602 reads (22%) | catalogued as COSV64950660; called by muse, mutect2, varscan2
- BRINP3 | c.288C>T p.F96= | Silent (SNP) | VAF 54/574 reads (9%) | catalogued as rs867310371, COSV66511698, COSV66528585; called by muse, mutect2
- BRPF3 | c.2583C>T p.P861= | Silent (SNP) | VAF 193/532 reads (36%) | catalogued as rs1488251502; called by muse, mutect2, varscan2
- C12orf40 | c.510C>T p.F170= | Silent (SNP) | VAF 62/306 reads (20%) | catalogued as COSV61132629; called by muse, mutect2, varscan2
- CABIN1 | c.5523C>T p.S1841= | Silent (SNP) | VAF 275/981 reads (28%) | called by muse, mutect2, varscan2
- CACNA1B | c.6198C>T p.S2066= | Silent (SNP) | VAF 172/892 reads (19%) | called by mutect2, varscan2
- CACNA1C | c.1263C>T p.F421= | Silent (SNP) | VAF 145/494 reads (29%) | catalogued as rs1464230364; called by muse, mutect2, varscan2
- CACNA1E | c.3348G>A p.Q1116= | Silent (SNP) | VAF 57/573 reads (10%) | called by muse, mutect2, varscan2
- CACNA1I | c.6663G>A p.R2221= | Silent (SNP) | VAF 129/519 reads (25%) | called by muse, mutect2, varscan2
- CACNA1S | c.2556G>A p.T852= | Silent (SNP) | VAF 36/334 reads (11%) | catalogued as rs1160627876, COSV62941690; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAMSAP2 | c.4227C>T p.F1409= (on ENST00000236925 / NM_001297707.2; = p.F1398= on NM_203459.3) | Silent (SNP) | VAF 29/288 reads (10%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.1614G>A p.S538= | Silent (SNP) | VAF 196/832 reads (24%) | catalogued as COSV50334686; called by muse, mutect2, varscan2
- CAPSL | c.222C>T p.V74= | Silent (SNP) | VAF 51/397 reads (13%) | catalogued as rs763014353, COSV101274216, COSV68439499; called by muse, mutect2, varscan2
- CCDC168 | c.7338C>T p.S2446= | Silent (SNP) | VAF 111/380 reads (29%) | catalogued as rs778718843; called by muse, mutect2, varscan2
- CCDC17 | c.1440G>A p.Q480= | Silent (SNP) | VAF 154/689 reads (22%) | catalogued as rs754158158; called by muse, mutect2, varscan2
- CCDC180 | c.4008C>T p.L1336= | Silent (SNP) | VAF 190/478 reads (40%) | catalogued as rs566889596; called by muse, mutect2, varscan2
- CCDC63 | c.360G>A p.L120= | Silent (SNP) | VAF 45/431 reads (10%) | called by muse, mutect2, varscan2
- CD163 | c.2625C>T p.I875= | Silent (SNP) | VAF 82/640 reads (13%) | catalogued as COSV63133215; called by muse, mutect2, varscan2
- CD48 | c.501G>A p.G167= | Silent (SNP) | VAF 66/522 reads (13%) | called by muse, mutect2, varscan2
- CDH22 | c.2130G>T p.A710= | Silent (SNP) | VAF 102/341 reads (30%) | catalogued as rs1382069746, COSV100953028; called by mutect2, varscan2
- CDH22 | c.1791C>T p.I597= | Silent (SNP) | VAF 228/937 reads (24%) | called by muse, mutect2, varscan2
- CDX1 | c.246C>T p.A82= | Silent (SNP) | VAF 130/601 reads (22%) | called by muse, varscan2
- CETN1 | c.453G>A p.R151= | Silent (SNP) | VAF 175/642 reads (27%) | catalogued as COSV100511236, COSV59121504; called by muse, mutect2, varscan2
- CGREF1 | c.31C>T p.L11= | Silent (SNP) | VAF 84/621 reads (14%) | called by muse, mutect2, varscan2
- CIITA | c.156C>T p.D52= | Silent (SNP) | VAF 131/425 reads (31%) | called by muse, mutect2, varscan2
- CILP2 | c.1710C>T p.I570= | Silent (SNP) | VAF 200/886 reads (23%) | catalogued as rs150610610; called by muse, mutect2, varscan2
- CLDN2 | c.42C>T p.G14= | Silent (SNP) | VAF 181/385 reads (47%) | called by muse, mutect2, varscan2
- COL12A1 | c.2628G>A p.G876= | Silent (SNP) | VAF 245/670 reads (37%) | catalogued as COSV59389535; called by muse, mutect2, varscan2
- COL23A1 | c.606G>A p.G202= | Silent (SNP) | VAF 71/519 reads (14%) | catalogued as COSV66793650; called by muse, mutect2, varscan2
- COL4A4 | c.2514A>G p.Q838= | Silent (SNP) | VAF 62/412 reads (15%) | called by muse, mutect2, varscan2
- COL6A5 | c.3450C>T p.L1150= | Silent (SNP) | VAF 129/333 reads (39%) | catalogued as rs1287841421, COSV55214905; called by muse, mutect2, varscan2
- COL6A6 | c.375G>A p.G125= | Silent (SNP) | VAF 263/636 reads (41%) | catalogued as rs768524817, COSV100649715; called by muse, mutect2, varscan2
- CPXM1 | c.1551C>T p.A517= | Silent (SNP) | VAF 159/786 reads (20%) | called by muse, mutect2, varscan2
- CRYAB | c.168G>T p.R56= | Silent (SNP) | VAF 64/454 reads (14%) | called by muse, mutect2, varscan2
- CSMD2 | c.3183G>A p.L1061= | Silent (SNP) | VAF 196/888 reads (22%) | called by muse, mutect2, varscan2
- CTCF | c.621C>T p.T207= | Silent (SNP) | VAF 187/539 reads (35%) | called by muse, mutect2, varscan2
- CTNND2 | c.222G>A p.Q74= | Silent (SNP) | VAF 179/567 reads (32%) | called by muse, mutect2, varscan2
- CYB561D1 | c.654C>T p.S218= | Silent (SNP) | VAF 119/489 reads (24%) | catalogued as COSV60205681; called by muse, mutect2, varscan2
- CYP11B1 | c.1026G>A p.Q342= | Silent (SNP) | VAF 256/747 reads (34%) | called by muse, mutect2, varscan2
- CYP2C9 | c.108C>T p.L36= | Silent (SNP) | VAF 199/574 reads (35%) | catalogued as rs1311013151; called by muse, mutect2, varscan2
- DCAF4L2 | c.450A>C p.A150= | Silent (SNP) | VAF 164/568 reads (29%) | catalogued as rs1388387406; called by muse, mutect2, varscan2
- DDX51 | c.1662G>A p.G554= | Silent (SNP) | VAF 83/300 reads (28%) | catalogued as rs1241912775, COSV100223005; called by muse, mutect2, varscan2
- DIAPH1 | c.1230C>T p.F410= | Silent (SNP) | VAF 54/337 reads (16%) | called by muse, mutect2, varscan2
- DIS3L2 | c.1872C>T p.F624= | Silent (SNP) | VAF 97/579 reads (17%) | called by muse, mutect2, varscan2
- DLG2 | c.1713C>T p.I571= | Silent (SNP) | VAF 70/541 reads (13%) | called by muse, mutect2, varscan2
- DNAJC16 | c.1761C>T p.F587= | Silent (SNP) | VAF 125/497 reads (25%) | catalogued as rs267598113; called by muse, mutect2, varscan2
- DOP1B | c.1452C>T p.F484= | Silent (SNP) | VAF 51/488 reads (10%) | catalogued as COSV101215777; called by muse, mutect2, varscan2
- E2F8 | c.1479C>T p.P493= | Silent (SNP) | VAF 99/692 reads (14%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1584G>A p.R528= | Silent (SNP) | VAF 161/719 reads (22%) | called by muse, mutect2, varscan2
- EPHA3 | c.267G>A p.R89= | Silent (SNP) | VAF 171/507 reads (34%) | catalogued as COSV60693678, COSV60700101; called by muse, mutect2, varscan2
- EPHA3 | c.2433G>A p.G811= | Silent (SNP) | VAF 79/736 reads (11%) | catalogued as COSV60709517; called by muse, mutect2, varscan2
- ESRRG | c.228G>A p.Q76= | Silent (SNP) | VAF 126/560 reads (23%) | catalogued as COSV63149998; called by muse, mutect2, varscan2
- EXO5 | c.615C>T p.L205= | Silent (SNP) | VAF 143/595 reads (24%) | catalogued as rs267598595; called by muse, mutect2, varscan2
- EXOC3L4 | c.210G>A p.K70= | Silent (SNP) | VAF 109/648 reads (17%) | called by muse, mutect2, varscan2
- FAM160A1 | c.1077C>T p.I359= | Silent (SNP) | VAF 71/229 reads (31%) | catalogued as rs970088187; called by muse, mutect2, varscan2
- FAM160A2 | c.2319C>T p.H773= (on ENST00000449352 / NM_001098794.2; = p.H787= on NM_032127.4) | Silent (SNP) | VAF 119/726 reads (16%) | called by muse, mutect2, varscan2
- FAT4 | c.11454C>T p.S3818= | Silent (SNP) | VAF 160/552 reads (29%) | called by muse, mutect2, varscan2
- FCER1A | c.624C>T p.I208= | Silent (SNP) | VAF 59/465 reads (13%) | called by muse, mutect2, varscan2
- FCHSD2 | c.822C>T p.S274= | Silent (SNP) | VAF 32/394 reads (8%) | catalogued as rs1473974125; called by muse, mutect2
- GABRA3 | c.405C>T p.I135= | Silent (SNP) | VAF 203/406 reads (50%) | catalogued as COSV64798950; called by muse, mutect2, varscan2
- GALNT16 | c.192C>T p.P64= | Silent (SNP) | VAF 119/395 reads (30%) | called by muse, mutect2, varscan2
- GCNT7 | c.786C>T p.F262= | Silent (SNP) | VAF 132/535 reads (25%) | catalogued as rs917511960; called by muse, mutect2, varscan2
- GLYATL2 | c.810A>G p.A270= | Silent (SNP) | VAF 61/461 reads (13%) | called by muse, mutect2, varscan2
- GNA15 | c.216G>A p.E72= | Silent (SNP) | VAF 218/804 reads (27%) | called by muse, mutect2, varscan2
- GNA15 | c.420G>A p.R140= | Silent (SNP) | VAF 160/783 reads (20%) | called by muse, mutect2, varscan2
- GPC2 | c.684G>A p.V228= | Silent (SNP) | VAF 94/615 reads (15%) | called by muse, mutect2, varscan2
- GPC5 | c.1029G>A p.R343= | Silent (SNP) | VAF 60/381 reads (16%) | catalogued as COSV65616879; called by muse, mutect2, varscan2
- GPR137 | c.843C>T p.F281= | Silent (SNP) | VAF 135/461 reads (29%) | catalogued as rs376840674; called by muse, mutect2, varscan2
- GPR50 | c.198C>T p.F66= | Silent (SNP) | VAF 128/290 reads (44%) | catalogued as COSV54439024; called by muse, mutect2, varscan2
- GPRC5C | c.1008C>T p.F336= (on ENST00000652232; = p.F291= on NM_018653.4) | Silent (SNP) | VAF 294/786 reads (37%) | catalogued as rs145203828; called by muse, mutect2, varscan2
- GRIK2 | c.1458G>A p.G486= | Silent (SNP) | VAF 106/304 reads (35%) | catalogued as rs867832831, COSV59715366; called by muse, mutect2, varscan2
- HAVCR1 | c.219G>A p.K73= | Silent (SNP) | VAF 93/540 reads (17%) | called by muse, mutect2, varscan2
- HBE1 | c.168G>A p.L56= | Silent (SNP) | VAF 49/425 reads (12%) | called by muse, mutect2, varscan2
- HEATR4 | c.1581G>A p.P527= | Silent (SNP) | VAF 61/448 reads (14%) | catalogued as rs141513108; called by muse, mutect2, varscan2
- HOXA10 | c.831G>A p.T277= | Silent (SNP) | VAF 382/969 reads (39%) | catalogued as rs778866706; called by muse, mutect2, varscan2
- IER5 | c.840C>T p.L280= | Silent (SNP) | VAF 71/652 reads (11%) | catalogued as rs552227691; called by muse, mutect2
- IFFO2 | c.894C>T p.I298= | Silent (SNP) | VAF 160/578 reads (28%) | catalogued as rs756774494; called by muse, varscan2
- IGDCC4 | c.2650C>T p.L884= | Silent (SNP) | VAF 127/693 reads (18%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.1542G>A p.Q514= | Silent (SNP) | VAF 108/364 reads (30%) | called by muse, mutect2, varscan2
- IGHA1 | c.918G>A p.K306= | Silent (SNP) | VAF 101/1478 reads (7%) | catalogued as rs773917605; called by muse, mutect2
- IGKV1-17 | c.24G>A p.Q8= | Silent (SNP) | VAF 175/740 reads (24%) | called by muse, mutect2, varscan2
- IGSF10 | c.2073G>A p.K691= | Silent (SNP) | VAF 247/610 reads (40%) | catalogued as rs1354373894; called by muse, mutect2, varscan2
- IL17B | c.483G>A p.G161= | Silent (SNP) | VAF 132/817 reads (16%) | called by muse, mutect2, varscan2
- IL18 | c.465A>C p.S155= | Silent (SNP) | VAF 106/424 reads (25%) | called by muse, mutect2, varscan2
- IRF4 | c.837A>C p.G279= | Silent (SNP) | VAF 40/518 reads (8%) | called by muse, mutect2
- KATNAL2 | c.1443G>A p.R481= (on ENST00000356157 / NM_001353899.1; = p.R409= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 121/474 reads (26%) | called by muse, mutect2, varscan2
- KCNB1 | c.1302G>A p.E434= | Silent (SNP) | VAF 158/584 reads (27%) | called by muse, mutect2, varscan2
- KCNC2 | c.1795C>A p.R599= | Silent (SNP) | VAF 47/342 reads (14%) | catalogued as COSV100129974; called by muse, mutect2, varscan2
- KCNJ5 | c.1239G>A p.R413= | Silent (SNP) | VAF 55/361 reads (15%) | called by muse, mutect2, varscan2
- KCNK10 | c.1497C>T p.S499= | Silent (SNP) | VAF 67/481 reads (14%) | catalogued as rs750203136; called by muse, mutect2, varscan2
- KIAA0319 | c.2238C>T p.D746= | Silent (SNP) | VAF 131/549 reads (24%) | catalogued as rs760008516; called by muse, mutect2, varscan2
- KIR2DS4 | c.618G>A p.V206= | Silent (SNP) | VAF 67/278 reads (24%) | called by muse, mutect2, varscan2
- KLHL13 | c.1548C>T p.I516= | Silent (SNP) | VAF 106/257 reads (41%) | catalogued as COSV53251415; called by muse, mutect2, varscan2
216 further variants in this file (0 protein-altering or splice-affecting, 185 silent, 31 other) are not listed here.
